CCDI case PBCMAI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/d6290ca3-5185-432d-a023-552d5378dad4

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 0.3 years (99 days).

Biospecimens (3 samples)
- Sample 0DV149: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DV14M: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DV14Z: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
